Somatic mutation profile of tumor specimen TCGA-CN-6011-01A (aliquot TCGA-CN-6011-01A-11D-1683-08) from TCGA case TCGA-CN-6011, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 57.5 years (21,016 days).
Specimen TCGA-CN-6011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 986df3b4-1e44-4ff4-b9a8-0cbed129128a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6011-10A (Blood Derived Normal), aliquot TCGA-CN-6011-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ec44146-f6c1-4ad4-89ad-b9ed569f3710

The open-access MAF lists 377 somatic variants for this specimen: 276 protein-altering or splice-affecting, 92 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 244, Silent 92, Nonsense Mutation 24, Intron 6, Splice Site 4, Splice Region 2, Frame Shift Ins 1, 3'UTR 1, RNA 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.614dup p.Y205* | Nonsense Mutation (INS) | VAF 14/40 reads (35%) | hotspot (GDC flag); catalogued as COSV52967845; called by mutect2, pindel, varscan2
- ABCB5 | c.2469G>T p.M823I (on ENST00000404938 / NM_001163941.2; = p.M378I on NM_178559.6) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as COSV99327219; called by muse, mutect2, varscan2
- ABRACL | c.62-1G>C p.X21_splice | Splice Site (SNP) | VAF 39/164 reads (24%) | catalogued as COSV62771253; called by muse, mutect2, varscan2
- AC105001.2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100134632, COSV59112062; called by muse, mutect2, varscan2
- ACAP2 | c.1738G>T p.V580L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV100461316; called by muse, mutect2, varscan2
- ACTN3 | c.1704C>G p.F568L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV100074057; called by muse, mutect2, varscan2
- ADGRG4 | c.1214C>G p.S405* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99794152; called by muse, mutect2, varscan2
- ADGRG6 | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs777617124, COSV99745577; called by muse, mutect2, varscan2
- ADH4 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV99039273, COSV99643974; called by muse, mutect2, varscan2
- AGPAT3 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV52370361, COSV99377071; called by muse, mutect2, varscan2
- AGR3 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1349814444, COSV60037148; called by muse, mutect2, varscan2
- ALAD | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1338526252, COSV99474505; called by muse, mutect2, varscan2
- AOC1 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100710565; called by muse, mutect2
- ARFRP1 | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100157339; called by muse, mutect2, varscan2
- ARHGAP29 | c.2863C>T p.R955C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.517); catalogued as rs141790636; called by muse, mutect2, varscan2
- ARHGAP45 | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.388); catalogued as COSV99297346; called by muse, mutect2, varscan2
- ASMTL | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV101187628; called by muse, mutect2, varscan2
- ASXL3 | c.4303G>C p.E1435Q | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as COSV99322973; called by muse, mutect2, varscan2
- ATF6B | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as rs377717271; called by muse, mutect2, varscan2
- ATP10B | c.4358G>A p.R1453H | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); catalogued as rs1263758447, COSV59150868; called by muse, mutect2, varscan2
- ATRX | c.7090C>T p.L2364F | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV64874510, COSV64874580; called by muse, mutect2, varscan2
- AVPR1B | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.561); catalogued as COSV100899293; called by muse, mutect2, varscan2
- BICC1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.105); catalogued as COSV65860933; called by muse, mutect2, varscan2
- BIRC6 | c.4933C>T p.Q1645* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV101427746; called by muse, mutect2
- BMPER | c.1221C>G p.N407K | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51813468, COSV99778678; called by muse, mutect2, varscan2
- BMPR1B | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.809); catalogued as COSV99215268; called by muse, mutect2, varscan2
- BNC2 | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 167/218 reads (77%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.473); catalogued as COSV101031863; called by muse, mutect2, varscan2
- BRIP1 | c.3344C>T p.S1115F | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as rs1419933310, COSV99369002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CA3 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53410254; called by muse, mutect2, varscan2
- CACNA1C | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1555832882, COSV100214579; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALCR | c.519C>T p.F173= | Splice Region (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100810308; called by muse, mutect2, varscan2
- CDC25B | c.1169G>A p.R390Q (on ENST00000245960 / NM_021873.3; = p.R376Q on NM_004358.4) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs770335566, COSV99847470; called by muse, mutect2, varscan2
- CDH2 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs758212729, COSV52276271, COSV52300234; called by muse, mutect2, varscan2
- CDH26 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99721624; called by muse, mutect2, varscan2
- CDH8 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as COSV100179199; called by muse, mutect2, varscan2
- CDKL2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771311219, COSV100276691; called by muse, mutect2, varscan2
- CEMIP2 | c.1457G>C p.G486A | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as COSV100987200; called by muse, mutect2, varscan2
- CENPF | c.4322C>T p.S1441L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100871441; called by muse, mutect2, varscan2
- CERKL | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV100182965; called by muse, mutect2, varscan2
- CFAP94 | c.1212G>A p.M404I (on ENST00000320267 / NM_001352064.2; = p.M410I on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100208798; called by muse, mutect2, varscan2
- CGN | c.2709G>C p.K903N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99641774; called by muse, mutect2, varscan2
- CHN1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV99788892; called by muse, mutect2, varscan2
- CILP | c.3527G>A p.R1176K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV99972689; called by muse, mutect2, varscan2
- CKM | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99675424, COSV99675550; called by muse, mutect2
- CNTN3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV99722983; called by muse, mutect2, varscan2
- COBL | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54345231, COSV99471004; called by muse, mutect2, varscan2
- COL1A2 | c.2546C>T p.S849F | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV51955373, COSV99798307; called by muse, mutect2, varscan2
- COPB2 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100300408; called by muse, mutect2, varscan2
- COX8A | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 116/265 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV100029249; called by muse, mutect2, varscan2
- CPAMD8 | c.976G>C p.E326Q (on ENST00000651564; = p.E279Q on NM_015692.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as COSV52232177, COSV99358875; called by muse, mutect2, varscan2
- CTLA4 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99865042; called by muse, mutect2, varscan2
- CYP4A11 | c.611A>C p.H204P | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV100152114; called by muse, mutect2, varscan2
- DDX54 | c.2247G>C p.K749N | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as COSV100013539; called by muse, mutect2, varscan2
- DDX60L | c.3656C>G p.S1219* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99486806; called by muse, mutect2, varscan2
- DIDO1 | c.6274G>C p.D2092H | Missense Mutation (SNP) | VAF 47/363 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV99824470; called by muse, mutect2, varscan2
- DLST | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV99471752; called by muse, mutect2, varscan2
- DLST | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV99471754; called by muse, mutect2, varscan2
- DMXL2 | c.5452C>G p.Q1818E | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV99195913; called by muse, mutect2, varscan2
- DNAH11 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV100176456; called by muse, mutect2, varscan2
- DNAH5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 26/339 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs779957324, COSV54206424; called by muse, mutect2
- DNAH7 | c.10075G>A p.D3359N | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs774760899, COSV56772164; called by muse, mutect2, varscan2
- DNAH8 | c.5481-1G>A p.X1827_splice | Splice Site (SNP) | VAF 18/55 reads (33%) | catalogued as rs1289181817, COSV100542917; called by muse, mutect2, varscan2
- DOCK2 | c.3385G>C p.E1129Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV99909768; called by muse, mutect2, varscan2
- DPP4 | c.1941C>G p.F647L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100858650; called by muse, mutect2, varscan2
- DRP2 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs778011942, COSV100871756; called by muse, mutect2, varscan2
- EGFLAM | c.2573C>G p.S858* (on ENST00000354891 / NM_001205301.2; = p.S850* on NM_152403.4) | Nonsense Mutation (SNP) | VAF 45/374 reads (12%) | catalogued as rs774283779, COSV100379667; called by muse, mutect2, varscan2
- EIF5 | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104370577, COSV99384640; called by muse, mutect2, varscan2
- EMC7 | c.412C>G p.L138V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99854683; called by muse, mutect2, varscan2
- EOLA1 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV100828387; called by muse, varscan2
- ERC2 | c.2314C>T p.Q772* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV55674984, COSV99880102; called by muse, mutect2, varscan2
- EXOC4 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV99552046; called by muse, mutect2, varscan2
- EYA3 | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100870192; called by muse, mutect2, varscan2
- FAM184A | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100137289; called by muse, mutect2, varscan2
- FAT4 | c.1173C>G p.N391K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101271764, COSV67897987; called by muse, mutect2, varscan2
- FCER1A | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.153); catalogued as COSV100929237; called by muse, mutect2, varscan2
- FLG2 | c.824G>A p.R275K | Missense Mutation (SNP) | VAF 95/128 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as rs758798815, COSV101165564; called by muse, mutect2, varscan2
- FLRT3 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV99425895; called by muse, mutect2, varscan2
- FNDC1 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs1427904597, COSV99794686; called by muse, mutect2, varscan2
- FOXD2 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58304045; called by muse, mutect2, varscan2
- G2E3 | c.1630C>G p.L544V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as COSV99249238; called by muse, mutect2, varscan2
- GABBR1 | c.1278G>C p.E426D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV63541262; called by muse, varscan2
- GABRG2 | c.1024C>A p.P342T (on ENST00000361925 / NM_001375343.1; = p.P302T on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/96 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100729435, COSV62721657; called by muse, mutect2, varscan2
- GARNL3 | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100149840, COSV59229083; called by muse, mutect2, varscan2
- GARNL3 | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV100149841; called by muse, mutect2, varscan2
- GLUD2 | c.1523C>G p.S508C | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100046567, COSV60151969; called by muse, mutect2, varscan2
- GNAS | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100005063; called by muse, mutect2, varscan2
- GPATCH2L | c.539C>G p.S180* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99833307; called by muse, mutect2, varscan2
- GPATCH3 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100658678; called by muse, varscan2
- GRHL1 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1385427526, COSV100258027, COSV61411495; called by muse, mutect2, varscan2
- GSX2 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482465, COSV58842799; called by muse, mutect2
- GUCY2D | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV54694156; called by muse, mutect2, varscan2
- GYS1 | c.1125C>A p.F375L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.963); catalogued as rs766357976, COSV99620317; called by muse, mutect2, varscan2
- H2AC13 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV100704298, COSV62440972; called by muse, mutect2, varscan2
- H3C6 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV64519644, COSV64519726; called by muse, mutect2, varscan2
- HAO2 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 25/93 reads (27%) | catalogued as rs1402470639, COSV100377722; called by muse, mutect2, varscan2
- HAUS6 | c.2530C>G p.L844V | Missense Mutation (SNP) | VAF 31/429 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs750186906, COSV100997719; called by muse, mutect2
- HDAC4 | c.2853A>G p.R951= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100612555; called by muse, mutect2, varscan2
- HFM1 | c.2210T>C p.F737S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99645179; called by muse, mutect2, varscan2
- HIVEP1 | c.368C>G p.S123* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV101044547; called by muse, mutect2, varscan2
- HIVEP2 | c.1153C>G p.L385V | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV99171411; called by muse, mutect2, varscan2
- HK2 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV99308433; called by muse, mutect2, varscan2
- IFIH1 | c.2599G>C p.E867Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV99718334; called by muse, mutect2, varscan2
- IFIH1 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV99718336; called by muse, varscan2
- IRGC | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.117); catalogued as rs1207095890, COSV54983753; called by muse, mutect2, varscan2
- ISL2 | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs753554538, COSV51957549, COSV99320462; called by muse, mutect2, varscan2
- ITPRID2 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.154); catalogued as COSV100237791; called by muse, mutect2, varscan2
- KCNH1 | c.2538G>C p.K846N (on ENST00000271751 / NM_172362.3; = p.K819N on NM_002238.4) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); catalogued as COSV99656929; called by muse, mutect2, varscan2
- KDM5B | c.3571C>T p.Q1191* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99349930; called by muse, mutect2, varscan2
- KDM5B | c.891G>C p.K297N | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV99349931; called by muse, mutect2, varscan2
- KIAA0825 | c.272G>C p.G91A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); catalogued as COSV100265495; called by muse, varscan2
- KIAA1109 | c.11179G>A p.E3727K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV99145457; called by muse, mutect2, varscan2
- KIF23 | c.2812G>A p.E938K (on ENST00000260363; = p.E834K on NM_004856.7) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99531764; called by muse, mutect2, varscan2
- KIF6 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99756808; called by muse, mutect2, varscan2
- KL | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101198966; called by muse, mutect2, varscan2
- KRT34 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs569309278, COSV101222523; called by muse, mutect2, varscan2
- KRTAP22-1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 40/213 reads (19%) | PolyPhen benign (0.073); catalogued as COSV100588881; called by muse, mutect2, varscan2
- LAMA4 | c.4447G>C p.E1483Q (on ENST00000230538 / NM_001105206.3; = p.E1476Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV100037449, COSV100037828; called by muse, mutect2, varscan2
- LARP1B | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1025971205, COSV52802417; called by muse, mutect2, varscan2
- LHPP | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100919178; called by muse, mutect2, varscan2
- LPAR4 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV101425065; called by muse, mutect2, varscan2
- LRCH3 | c.660G>C p.L220F | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100604907, COSV58395408; called by muse, mutect2, varscan2
- LRP1B | c.2267A>G p.Y756C | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101249995, COSV101250852; called by muse, mutect2, varscan2
- LRRK2 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.843); catalogued as COSV100108851; called by muse, mutect2, varscan2
- LSAMP | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.241); catalogued as COSV100368743; called by muse, mutect2, varscan2
- MAB21L2 | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as COSV100461875; called by muse, mutect2, varscan2
- MAB21L3 | c.218C>A p.T73K | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV101046281; called by muse, mutect2, varscan2
- MAGEB16 | c.527C>G p.T176S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.101); catalogued as COSV101303262; called by muse, mutect2, varscan2
- MAP3K13 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs759720581, COSV99406261; called by muse, mutect2, varscan2
- MAPRE1 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as COSV100980379; called by muse, mutect2, varscan2
- MBP | c.222G>C p.K74N | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100592388; called by muse, mutect2, varscan2
- MBTPS1 | c.2914G>A p.V972M | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100597296; called by muse, mutect2, varscan2
- MCOLN2 | c.1114C>G p.L372V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV99393539; called by muse, mutect2
- METTL1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs372769807; called by muse, mutect2, varscan2
- MEX3D | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1164258377, COSV101183453; called by muse, mutect2, varscan2
- MFSD2A | c.1429G>A p.E477K (on ENST00000372809 / NM_001136493.3; = p.E464K on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV100861594; called by muse, mutect2, varscan2
- MRTFA | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs773029783, COSV100843792; called by muse, varscan2
- MS4A14 | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100279941; called by muse, varscan2
- MS4A14 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100279942; called by muse, varscan2
- MTMR12 | c.1807G>C p.D603H | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99373300; called by muse, mutect2, varscan2
- MTUS2 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs533342793, COSV101462043, COSV70922131; called by muse, mutect2, varscan2
- MYH11 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1167460119, COSV100257482; called by muse, mutect2, varscan2
- MYH11 | c.2130C>G p.I710M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257483; called by muse, mutect2, varscan2
- MYO10 | c.4600C>T p.R1534* | Nonsense Mutation (SNP) | VAF 21/183 reads (11%) | catalogued as rs868753258, COSV57025712; called by muse, mutect2, varscan2
- MYO16 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99193429; called by muse, mutect2, varscan2
- NAF1 | c.614C>G p.S205* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV99918855; called by muse, mutect2
- NBEAL2 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99434075; called by muse, mutect2, varscan2
- NDUFA3 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1458006023, COSV99499791; called by muse, mutect2, varscan2
- NFKB1 | c.2647G>A p.E883K (on ENST00000394820 / NM_001382627.1; = p.E884K on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.766); catalogued as rs748249744, COSV99896539; called by muse, mutect2, varscan2
- NHS | c.2799G>C p.L933F | Missense Mutation (SNP) | VAF 88/107 reads (82%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101196344; called by muse, mutect2, varscan2
- NOL12 | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV100767115, COSV100767153; called by muse, mutect2, varscan2
- NOL8 | c.3253G>C p.E1085Q | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100694412; called by muse, mutect2, varscan2
- NOTCH1 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as rs775602958, COSV53041636, COSV53092037; called by muse, varscan2
- NUDT19 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV101229174; called by muse, mutect2, varscan2
- NUP214 | c.4538C>T p.S1513L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.173); catalogued as COSV100845073; called by muse, mutect2, varscan2
- OBSCN | c.14893G>A p.D4965N | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264650038, COSV99471380; called by muse, mutect2, varscan2
- OR2K2 | c.287C>G p.S96C (on ENST00000374428; = p.S67C on NM_205859.2) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV57018680; called by muse, mutect2, varscan2
- OR2T5 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as COSV100822163; called by muse, varscan2
- OR4A16 | c.838T>A p.L280M | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV100124963; called by muse, mutect2, varscan2
- OR4K5 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100262082; called by muse, mutect2, varscan2
- OR51A7 | c.750C>A p.F250L | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100834572, COSV63788937; called by muse, mutect2, varscan2
- OR52K1 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100297546, COSV100297765; called by muse, mutect2, varscan2
- OR5A2 | c.185T>C p.F62S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100119646; called by muse, mutect2, varscan2
- OR5B3 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV100511789; called by muse, mutect2, varscan2
- OR8H3 | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs1281451566, COSV100538744, COSV57907222, COSV57907840; called by muse, mutect2, varscan2
- PBX3 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV100655221, COSV100655261; called by muse, mutect2, varscan2
- PCDH15 | c.1738G>T p.A580S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.961); catalogued as COSV100213918, COSV100214304; called by muse, mutect2, varscan2
- PCDHB7 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV50754216; called by muse, mutect2, varscan2
- PDZRN4 | c.2894G>A p.R965Q (on ENST00000402685 / NM_001164595.2; = p.R707Q on NM_013377.4) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.226); catalogued as rs1422938315, COSV54191692; called by muse, mutect2, varscan2
- PGBD2 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV100251829; called by muse, mutect2, varscan2
- PGR | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1175582391, COSV54804760, COSV99678432; called by muse, mutect2, varscan2
- PIGO | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as rs768552303, COSV53055223; called by muse, mutect2, varscan2
- PLD1 | c.2949C>G p.F983L | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV100643751; called by muse, varscan2
- PLSCR4 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV100724079; called by muse, mutect2, varscan2
- PLXNB3 | c.1572C>G p.H524Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs782618067, COSV100737036, COSV100737083; called by muse, mutect2, varscan2
- POGLUT1 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99809371; called by muse, mutect2, varscan2
- POU4F2 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99850226; called by muse, mutect2, varscan2
- PREPL | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.46); PolyPhen benign (0.212); catalogued as COSV99575866; called by muse, mutect2, varscan2
- PRR14L | c.5804A>G p.Y1935C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs746194422, COSV100392053; called by muse, mutect2, varscan2
- PRR16 | c.748C>A p.P250T (on ENST00000407149 / NM_001300783.2; = p.P227T on NM_016644.2) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65408490; called by muse, mutect2, varscan2
- PSG7 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 75/90 reads (83%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs887148891, COSV101343172; called by muse, mutect2, varscan2
- PSMC2 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.063); catalogued as COSV99485094; called by muse, mutect2, varscan2
- PTGER3 | c.909G>C p.L303F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100138010; called by muse, mutect2, varscan2
- RASGRF1 | c.2542C>T p.Q848* | Nonsense Mutation (SNP) | VAF 52/115 reads (45%) | catalogued as COSV101174259; called by muse, mutect2, varscan2
- RBM26 | c.2733+2T>C p.X911_splice (on ENST00000438737 / NM_001366735.2; = p.X884_splice on NM_022118.5) | Splice Site (SNP) | VAF 10/13 reads (77%) | catalogued as COSV57395252; called by muse, mutect2, varscan2
- RHPN2 | c.1079C>G p.T360S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99576927; called by muse, varscan2
- RNASEH1 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100176980; called by muse, mutect2, varscan2
- RNF10 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV100378422; called by muse, mutect2, varscan2
- RNF10 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100378425; called by muse, mutect2, varscan2
- RNF214 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100326427, COSV56121578; called by muse, mutect2, varscan2
- RP1 | c.1426C>G p.Q476E | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99606001; called by muse, mutect2, varscan2
- RPS20 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV99154714; called by muse, mutect2, varscan2
- RPS6KA1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as COSV100942866; called by muse, mutect2, varscan2
- RYR2 | c.12367G>A p.E4123K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV100767319; called by muse, mutect2, varscan2
- S100A7A | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV61329979; called by muse, mutect2, varscan2
- SBF1 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62370009; called by muse, mutect2, varscan2
- SCD5 | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV51102340, COSV99262192; called by muse, mutect2, varscan2
- SCML1 | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV101193889; called by muse, mutect2, varscan2
- SCN3A | c.3166G>C p.E1056Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); catalogued as COSV51811807, COSV51825859, COSV99325458; called by muse, mutect2, varscan2
- SCRN3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.438); catalogued as rs1452175705, COSV99767035; called by muse, mutect2, varscan2
- SDC2 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.255); catalogued as COSV100142813; called by muse, mutect2, varscan2
- SEC61A1 | c.152T>A p.F51Y | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV99684664; called by muse, mutect2, varscan2
- SECISBP2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs147681365; called by muse, mutect2, varscan2
- SEL1L | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100377589; called by muse, mutect2, varscan2
- SEMA5A | c.1274-1G>C p.X425_splice | Splice Site (SNP) | VAF 30/168 reads (18%) | catalogued as COSV101226849, COSV101227324; called by muse, mutect2, varscan2
- SETD3 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100074782; called by muse, mutect2, varscan2
- SETDB1 | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.238); catalogued as COSV99643511; called by muse, mutect2, varscan2
- SGCZ | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.082); catalogued as COSV101166432, COSV101168919; called by muse, mutect2, varscan2
- SLC15A4 | c.1147C>G p.L383V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV99903357, COSV99903362; called by muse, mutect2, varscan2
- SLC17A7 | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99676655; called by muse, mutect2, varscan2
- SLC22A3 | c.1041G>C p.M347I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.241); catalogued as rs200083406, COSV99278222, COSV99279429; called by muse, mutect2, varscan2
- SLC30A4 | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99970080; called by muse, mutect2, varscan2
- SLC30A6 | c.1204C>G p.L402V | Missense Mutation (SNP) | VAF 88/112 reads (79%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.039); catalogued as rs762348812, COSV99249211; called by muse, mutect2, varscan2
- SNX29 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); catalogued as COSV100026932; called by muse, mutect2, varscan2
- SPATA45 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100260265; called by muse, mutect2, varscan2
- SPATA5 | c.2119A>G p.R707G | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99914535; called by muse, mutect2, varscan2
- SPINT1 | c.1294G>A p.E432K (on ENST00000344051 / NM_181642.3; = p.E416K on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100688836; called by muse, mutect2, varscan2
- SRGAP1 | c.351G>C p.L117F | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100754166; called by muse, mutect2, varscan2
- SSRP1 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV99554679; called by muse, mutect2
- ST8SIA2 | c.894G>C p.L298F | Missense Mutation (SNP) | VAF 3/18 reads (17%) | PolyPhen probably damaging (0.922); catalogued as COSV99184350; called by muse, mutect2
- STRN3 | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.074); catalogued as rs758836299, COSV100670199; called by muse, mutect2, varscan2
- STX7 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 35/151 reads (23%) | catalogued as rs970685870, COSV100908372; called by muse, varscan2
- SYCP2 | c.4276G>C p.E1426Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs377589640, COSV100697931, COSV62768998; called by muse, mutect2, varscan2
- SYNE1 | c.7225A>T p.K2409* (on ENST00000367255 / NM_182961.4; = p.K2416* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 161/318 reads (51%) | catalogued as COSV99550882; called by muse, mutect2, varscan2
- SYNE1 | c.3959C>A p.T1320K (on ENST00000367255 / NM_182961.4; = p.T1327K on NM_033071.3) | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.489); catalogued as COSV55092793, COSV99550888; called by muse, mutect2, varscan2
- SYNE2 | c.12213G>C p.L4071F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV100646460; called by muse, mutect2
- TAT | c.291G>C p.M97I | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV100587456, COSV100587590; called by muse, mutect2, varscan2
- TDRD5 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as COSV99675315; called by muse, mutect2, varscan2
- THBS2 | c.946A>C p.N316H | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.794); catalogued as COSV100827522; called by muse, mutect2, varscan2
- TIMM13 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99295837; called by muse, mutect2, varscan2
- TKTL2 | c.993A>T p.K331N | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99761031; called by muse, mutect2, varscan2
- TLK1 | c.1940A>G p.E647G | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as COSV100687217; called by muse, mutect2, varscan2
- TOE1 | c.1250G>T p.R417I | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100516959, COSV59153521; called by muse, mutect2, varscan2
- TOP1MT | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV100239124, COSV61316890; called by muse, mutect2, varscan2
- TOP2B | c.2320G>A p.E774K (on ENST00000264331 / NM_001330700.2; = p.E769K on NM_001068.3) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99979004; called by muse, mutect2, varscan2
- TP63 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV53207727, COSV53221611; called by muse, mutect2
- TRIM51 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.053); catalogued as COSV99792070; called by muse, mutect2, varscan2
- TRIM9 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100030317; called by muse, mutect2, varscan2
- TTC17 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV99234543; called by muse, mutect2, varscan2
- TTC23L | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV101551094; called by muse, mutect2, varscan2
- TTN | c.14251G>A p.E4751K (on ENST00000591111; = p.E3824K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | PolyPhen benign (0.194); catalogued as COSV60224238, COSV60379338; called by muse, mutect2, varscan2
- TTN | c.6355G>A p.E2119K (on ENST00000591111; = p.E2073K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | PolyPhen probably damaging (0.994); catalogued as CM1514658, COSV100591218; called by muse, mutect2, varscan2
- UBR4 | c.7681G>A p.E2561K | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs1239601103, COSV100920076; called by muse, mutect2, varscan2
- UNC13C | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV52839983, COSV52874845, COSV99510493; called by muse, mutect2, varscan2
- UNC13C | c.3862G>A p.D1288N | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52862074; called by muse, mutect2, varscan2
- VPS41 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100053445; called by muse, mutect2, varscan2
- VPS45 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs782191450, COSV100964850; called by muse, mutect2, varscan2
- WASHC2C | c.3163G>A p.E1055K (on ENST00000336378; = p.E1034K on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs1180693308; called by muse, mutect2, varscan2
- WDR70 | c.1658A>G p.K553R | Missense Mutation (SNP) | VAF 126/235 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV99457200; called by muse, mutect2, varscan2
- WNT3 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1483494147, COSV56646081; called by muse, mutect2, varscan2
- XIRP2 | c.9496G>C p.E3166Q (on ENST00000628543; = p.E3341Q on NM_152381.6) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV54684583; called by muse, mutect2, varscan2
- XPO4 | c.708G>C p.W236C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99687868; called by muse, mutect2
- ZBTB46 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55512548, COSV99828671; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1364G>C p.R455T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.585); catalogued as rs1403439859, COSV54293110, COSV54294129; called by muse, mutect2, varscan2
- ZDHHC5 | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs555314929, COSV54706618; called by muse, mutect2, varscan2
- ZFYVE9 | c.3952G>A p.E1318K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.309); catalogued as COSV99819246; called by muse, mutect2, varscan2
- ZMYM1 | c.2114G>C p.G705A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100720873, COSV63253665; called by muse, mutect2, varscan2
- ZMYM1 | c.2202G>C p.K734N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100720874; called by muse, mutect2, varscan2
- ZNF106 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.075); catalogued as COSV99782060; called by muse, mutect2, varscan2
- ZNF112 | c.2425C>T p.Q809* (on ENST00000337401 / NM_001083335.2; = p.Q803* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 38/146 reads (26%) | catalogued as COSV100495433; called by muse, mutect2, varscan2
- ZNF208 | c.1831T>A p.C611S | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101236684; called by muse, mutect2, varscan2
- ZNF212 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60025929; called by muse, mutect2, varscan2
- ZNF251 | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99478072; called by muse, mutect2, varscan2
- ZNF433 | c.873C>G p.F291L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100794904; called by muse, mutect2, varscan2
- ZNF470 | c.618G>C p.K206N | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100401033, COSV57968422; called by muse, mutect2, varscan2
- ZNF471 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100340303; called by muse, mutect2, varscan2
- ZNF555 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV100514499; called by muse, mutect2, varscan2
- ZNF560 | c.1516C>G p.H506D | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100038182; called by muse, mutect2, varscan2
- ZNF618 | c.1134T>G p.F378L (on ENST00000374126 / NM_001318042.2; = p.F285L on NM_133374.2) | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.005); catalogued as COSV99928970; called by muse, mutect2, varscan2
- ZNF835 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV101606243; called by muse, varscan2
- ZYG11B | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV53757371, COSV99596674; called by muse, mutect2, varscan2
- CYP2J2 | c.237dup p.S80* | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- IGHV1-24 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- LPA | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR6C74 | c.217del p.T73Lfs*62 | Frame Shift Del (DEL) | VAF 52/233 reads (22%) | called by mutect2, pindel, varscan2
- TPTE | c.313G>A p.D105N (on ENST00000618007 / NM_199261.4; = p.D87N on NM_199259.4) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AC100868.1 | c.1749G>T p.V583= | Silent (SNP) | VAF 43/74 reads (58%) | catalogued as COSV99225073; called by muse, mutect2, varscan2
- ACOT13 | c.213T>C p.A71= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100015810; called by muse, mutect2, varscan2
- ACTL7B | c.855C>T p.D285= | Silent (SNP) | VAF 82/114 reads (72%) | catalogued as rs754233470, COSV65926812, COSV65927618; called by muse, mutect2, varscan2
- ADGRL3 | c.3570C>T p.F1190= (on ENST00000506720 / NM_001322402.2; = p.F1122= on NM_015236.6) | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV72230690; called by muse, mutect2, varscan2
- AHNAK | c.14805G>A p.P4935= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as rs149805243; called by muse, mutect2, varscan2
- AKT1 | c.591C>T p.T197= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs763782135, COSV100837899; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARG2 | c.78G>A p.V26= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs748036110, COSV99937341; called by muse, varscan2
- ARMC9 | c.1479G>A p.K493= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as COSV100589458; called by muse, mutect2, varscan2
- BBS9 | c.1416C>T p.F472= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV99625478; called by muse, mutect2, varscan2
- BPIFB2 | c.1056C>T p.F352= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV50064347; called by muse, mutect2, varscan2
- BPIFC | c.885C>T p.F295= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100300671; called by muse, mutect2, varscan2
- BTD | c.171C>T p.I57= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV100329391; called by muse, mutect2, varscan2
- CAVIN4 | c.255C>T p.I85= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV100293073, COSV56866583; called by muse, mutect2, varscan2
- CCDC28A | c.345G>A p.Q115= | Silent (SNP) | VAF 60/113 reads (53%) | catalogued as rs1192649303, COSV100236222; called by muse, mutect2, varscan2
- CEP128 | c.2799G>A p.E933= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV99823394; called by muse, mutect2, varscan2
- CEP170 | c.870G>C p.G290= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100316272; called by muse, mutect2, varscan2
- COL4A3 | c.3507G>A p.K1169= | Silent (SNP) | VAF 55/83 reads (66%) | catalogued as COSV100516631; called by muse, mutect2, varscan2
- CRELD1 | c.414C>T p.S138= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as COSV99925488; called by muse, mutect2, varscan2
- CRNN | c.1353G>C p.V451= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV99663875; called by muse, mutect2, varscan2
- CRYZ | c.120C>T p.I40= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV61719004; called by muse, mutect2, varscan2
- CSPG4 | c.873C>T p.I291= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100413252; called by muse, mutect2, varscan2
- CYFIP2 | c.1878C>T p.F626= (on ENST00000616178 / NM_001291722.2; = p.F601= on NM_014376.4) | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV100555462; called by muse, mutect2, varscan2
- DACT3 | c.1704C>T p.D568= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100340139; called by muse, mutect2, varscan2
- DBP | c.103C>T p.L35= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99320481; called by muse, mutect2
- DENND5B | c.2943C>A p.T981= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV100170750; called by muse, mutect2, varscan2
- DNAH7 | c.7146G>C p.V2382= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100413579; called by muse, mutect2, varscan2
- EPHX4 | c.45C>T p.L15= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100952621; called by muse, mutect2, varscan2
- FBLL1 | c.507C>T p.I169= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as COSV100606116; called by muse, mutect2, varscan2
- FCF1 | c.120C>G p.P40= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100115861; called by muse, mutect2, varscan2
- GJD4 | c.282C>G p.V94= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV100397054; called by muse, mutect2, varscan2
- GLG1 | c.1083G>C p.L361= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV99215180; called by muse, mutect2, varscan2
- GPATCH3 | c.990G>A p.E330= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV100658677; called by muse, mutect2, varscan2
- HAS1 | c.1320C>T p.G440= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV55790038; called by muse, mutect2, varscan2
- HIVEP3 | c.6696G>C p.L2232= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs1444694674, COSV99911237; called by muse, mutect2, varscan2
- HYDIN | c.366G>A p.L122= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as COSV55478104; called by muse, mutect2, varscan2
- IFIH1 | c.975C>T p.I325= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV99718337; called by muse, varscan2
- IKZF1 | c.468G>A p.Q156= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV58781106; called by muse, mutect2
- KCNA4 | c.153C>G p.V51= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100068425, COSV60251501; called by muse, mutect2, varscan2
- KCNN3 | c.792A>G p.Q264= | Silent (SNP) | VAF 75/95 reads (79%) | catalogued as COSV99677165; called by muse, mutect2, varscan2
- KIAA2026 | c.291C>T p.L97= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV52390702; called by muse, mutect2
- KL | c.3012G>A p.S1004= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs139874106; called by muse, mutect2, varscan2
- KNL1 | c.2580G>A p.Q860= (on ENST00000346991 / NM_170589.5; = p.Q834= on NM_144508.5) | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV100705795; called by muse, mutect2, varscan2
- LUZP4 | c.402G>A p.G134= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV100904821; called by muse, mutect2, varscan2
- MAGEB16 | c.528C>A p.T176= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV101303263; called by muse, mutect2, varscan2
- MAP11 | c.1335G>A p.R445= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as COSV100385319; called by muse, mutect2, varscan2
- MAP3K19 | c.3705C>A p.A1235= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100207954; called by muse, mutect2, varscan2
- MFSD2B | c.1479G>T p.L493= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV100600952; called by muse, varscan2
- MICAL1 | c.1260G>A p.V420= | Silent (SNP) | VAF 32/336 reads (10%) | catalogued as COSV100668382; called by muse, mutect2
- MME | c.630G>A p.K210= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100852168; called by muse, mutect2, varscan2
- MMRN1 | c.2967G>A p.S989= | Silent (SNP) | VAF 38/56 reads (68%) | catalogued as rs762745325, COSV53333481; called by muse, mutect2, varscan2
- MRTFA | c.1086C>A p.I362= | Silent (SNP) | VAF 36/54 reads (67%) | catalogued as COSV100843791, COSV100844198; called by muse, varscan2
- MS4A3 | c.205C>T p.L69= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV99614409; called by muse, mutect2, varscan2
- MTERF1 | c.819G>C p.L273= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100699529; called by muse, mutect2, varscan2
- MYO7B | c.2304C>T p.L768= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101267832, COSV101268095; called by muse, mutect2
- NCK2 | c.840C>T p.F280= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs374552067, COSV51892045; called by muse, mutect2, varscan2
- NCLN | c.258C>T p.L86= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1197057662, COSV99859620; called by muse, mutect2, varscan2
- NCOR2 | c.567G>A p.Q189= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as COSV100656673; called by muse, mutect2, varscan2
- OR4D9 | c.675G>C p.L225= | Silent (SNP) | VAF 35/210 reads (17%) | catalogued as COSV100259662, COSV100259901; called by muse, mutect2, varscan2
- OR7A10 | c.462G>C p.L154= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV99932349; called by muse, mutect2
- PDCD11 | c.1326T>C p.A442= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100874219; called by muse, mutect2, varscan2
- PLAU | c.309G>A p.T103= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs764563021, COSV101032216; called by muse, mutect2, varscan2
- PRKCG | c.1944G>A p.T648= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV99668421; called by muse, mutect2, varscan2
- RAB31 | c.21C>G p.L7= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV101640156; called by muse, mutect2, varscan2
- RAD51C | c.66G>A p.A22= | Silent (SNP) | VAF 41/61 reads (67%) | catalogued as rs876660695, COSV99541210; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RHOJ | c.465C>T p.L155= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100370015; called by muse, mutect2, varscan2
- RIMBP2 | c.1293C>T p.I431= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs889264671, COSV55464101, COSV55479457; called by muse, mutect2, varscan2
- RRS1 | c.471G>A p.L157= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99397511; called by muse, mutect2, varscan2
- RSPH4A | c.342G>C p.T114= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99993885; called by muse, mutect2, varscan2
- SCML1 | c.396C>G p.S132= (on ENST00000380041 / NM_001037540.3; = p.S105= on NM_006746.6) | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV101193890; called by muse, mutect2, varscan2
- SCN1A | c.1608C>T p.F536= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as rs1351109657, COSV57684378; called by muse, mutect2, varscan2
- SCYL1 | c.591C>T p.V197= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99533665; called by muse, mutect2, varscan2
- SEMA4D | c.936C>T p.L312= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV100357848; called by muse, mutect2, varscan2
- SEMA4D | c.117G>A p.L39= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100357851; called by muse, mutect2, varscan2
- SEMA4G | c.2019G>C p.V673= (on ENST00000370250; = p.V678= on NM_017893.3) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99271806; called by muse, mutect2, varscan2
- SIVA1 | c.527G>A p.*176= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs766093404, COSV100328433; called by muse, mutect2, varscan2
- SLC13A5 | c.577C>T p.L193= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV53425161, COSV99545622; called by muse, mutect2, varscan2
- SLC22A3 | c.1506C>T p.I502= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV99278225; called by muse, mutect2, varscan2
- SRF | c.1137C>T p.L379= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV99541680; called by muse, mutect2, varscan2
- SYBU | c.63T>C p.S21= (on ENST00000276646 / NM_001099754.2; = p.S20= on NM_017786.6) | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV99405603; called by muse, mutect2, varscan2
- TAAR6 | c.835T>C p.L279= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV99256430; called by muse, mutect2, varscan2
- TMPRSS11E | c.78C>T p.F26= | Silent (SNP) | VAF 43/314 reads (14%) | catalogued as COSV100542163; called by muse, mutect2, varscan2
- TNFRSF11B | c.366G>A p.R122= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99816337, COSV99816980; called by muse, varscan2
- TNS3 | c.4101C>G p.L1367= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV60790785; called by muse, mutect2
- TPTE | c.312G>A p.L104= (on ENST00000618007 / NM_199261.4; = p.L86= on NM_199259.4) | Silent (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- TRPM1 | c.1569G>A p.P523= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs201426913, COSV56643800; called by muse, mutect2
- TSKS | c.1683C>T p.L561= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV99882762; called by muse, mutect2, varscan2
- USH2A | c.8829G>C p.V2943= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100228002, COSV100238854, COSV100239689; called by muse, mutect2, varscan2
- VARS1 | c.2094C>G p.L698= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100791767; called by muse, mutect2, varscan2
- VEPH1 | c.2490C>G p.T830= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV100747274, COSV62877270; called by muse, mutect2, varscan2
- XKR7 | c.1410G>A p.T470= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs746729361, COSV101629225, COSV101629301; called by muse, mutect2, varscan2
- XYLT1 | c.2199C>T p.D733= | Silent (SNP) | VAF 127/236 reads (54%) | catalogued as COSV99759980; called by muse, mutect2, varscan2
- ZNF251 | c.813G>A p.G271= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as COSV99478076; called by muse, mutect2, varscan2
- BSG | chr19:571571 C>T | 5'Flank (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100344404, COSV100344406; called by muse, mutect2, varscan2
- CLCN5 | c.17-38805C>G | Intron (SNP) | VAF 11/12 reads (92%) | catalogued as COSV101066882; called by muse, mutect2, varscan2
- FAM174A | c.*1G>C | 3'UTR (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100444209; called by muse, mutect2, varscan2
- NACA | c.70+4481G>T | Intron (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100771043; called by muse, mutect2, varscan2
- NRG1 | c.502+31025G>A | Intron (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99827333; called by muse, mutect2, varscan2
- PARGP1 | n.1027G>C | RNA (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- RABGGTB | c.309+172C>G | Intron (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100174890; called by muse, mutect2, varscan2
- SPTBN4 | c.5915+39G>A | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100149820; called by muse, mutect2, varscan2
- TRIP12 | c.99-837T>A | Intron (SNP) | VAF 68/108 reads (63%) | catalogued as COSV99389108; called by muse, mutect2, varscan2
